Somatic mutation profile of tumor specimen TCGA-CV-A45U-01A (aliquot TCGA-CV-A45U-01A-12D-A24D-08) from TCGA case TCGA-CV-A45U, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 59.5 years (21,746 days).
Specimen TCGA-CV-A45U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f102a06f-f9fe-4f2e-85e7-3be4d61ad468.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A45U-10A (Blood Derived Normal), aliquot TCGA-CV-A45U-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5063faf0-e9a7-4a7c-9528-461d9820a9f5

The open-access MAF lists 212 somatic variants for this specimen: 146 protein-altering or splice-affecting, 63 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 63, Nonsense Mutation 15, Frame Shift Del 2, RNA 2, Intron 1, Splice Site 1, In Frame Del 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 41/73 reads (56%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAT | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100528643; called by muse, mutect2
- ABCC1 | c.3157C>A p.L1053M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100579637, COSV60694994; called by muse, mutect2, varscan2
- ACSF3 | c.80G>T p.R27I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.034); catalogued as COSV100441357, COSV58077846; called by muse, mutect2, varscan2
- AP002748.5 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV100567949; called by muse, mutect2
- ARSK | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV101187546; called by muse, mutect2, varscan2
- ASB3 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV99712062; called by muse, mutect2, varscan2
- ASXL1 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs199602042, COSV100039377; called by muse, mutect2, varscan2
- BPNT1 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.208); catalogued as COSV100435676; called by muse, mutect2
- CACNA2D4 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); catalogued as COSV99765725; called by muse, mutect2, varscan2
- CATSPERG | c.3416G>A p.S1139N | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.005); catalogued as rs1489665271, COSV99286548; called by muse, mutect2, varscan2
- CCDC18 | c.1879G>C p.E627Q (on ENST00000343253 / NM_001306076.1; = p.E628Q on NM_206886.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as COSV100159618, COSV100159864; called by muse, mutect2, varscan2
- CCDC82 | c.1001G>T p.S334I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.412); catalogued as COSV99567336; called by muse, mutect2
- CCNF | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99563659; called by muse, mutect2, varscan2
- CCNT2 | c.1871A>G p.N624S | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs762671853, COSV99750692; called by muse, mutect2, varscan2
- CD163L1 | c.2663G>C p.R888T | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.953); catalogued as COSV100550114; called by muse, mutect2
- CDC42BPA | c.4411G>C p.D1471H (on ENST00000334218 / NM_001366019.2; = p.D1458H on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100505171; called by muse, mutect2, varscan2
- CDC42BPB | c.3485C>T p.S1162L | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100775459; called by muse, mutect2, varscan2
- CECR2 | c.3773C>T p.S1258L (on ENST00000342247 / NM_001290047.2; = p.S1074L on NM_001290046.1) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as COSV99378047; called by muse, mutect2, varscan2
- CELSR2 | c.4619G>A p.R1540Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs150273941; called by muse, mutect2, varscan2
- CEP89 | c.298A>T p.R100W | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99993503; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 27/118 reads (23%) | catalogued as COSV100291898; called by muse, mutect2, varscan2
- CHD4 | c.1815del p.K605Nfs*5 (on ENST00000357008 / NM_001363606.2; = p.K618Nfs*5 on NM_001273.5) | Frame Shift Del (DEL) | VAF 26/179 reads (15%) | catalogued as COSV100538087; called by mutect2, pindel, varscan2
- CHST5 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60337524; called by muse, mutect2, varscan2
- CMTR1 | c.1885A>T p.T629S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100990873; called by muse, mutect2, varscan2
- COL4A4 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100306915; called by muse, mutect2, varscan2
- CSH2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV100400223; called by muse, mutect2
- CSMD1 | c.2686G>A p.V896M (on ENST00000520002; = p.V895M on NM_033225.6) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369227633; called by muse, mutect2, varscan2
- CTH | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100697086, COSV61009801; called by muse, mutect2, varscan2
- CUBN | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV100910593, COSV64701760; called by muse, mutect2, varscan2
- DDX24 | c.9G>T p.L3F | Missense Mutation (SNP) | VAF 112/219 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.166); catalogued as COSV100427956; called by muse, mutect2, varscan2
- DENND3 | c.2859G>A p.M953I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.379); catalogued as COSV99371024; called by muse, mutect2, varscan2
- DICER1 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.912); catalogued as COSV100602135; called by muse, mutect2
- DLST | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 22/130 reads (17%) | catalogued as COSV99471989; called by muse, mutect2, varscan2
- DMGDH | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs765873369, COSV99669041; called by muse, mutect2, varscan2
- DNAH5 | c.11846T>G p.L3949R | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1334354600, COSV54201621, COSV54257873; called by muse, mutect2, varscan2
- DYSF | c.1326G>A p.W442* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as rs1274165804, COSV99247386; called by muse, mutect2, varscan2
- EMILIN3 | c.2162G>A p.R721K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60034905; called by muse, mutect2, varscan2
- ETV7 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100339210; called by muse, mutect2, varscan2
- FAM47C | c.848G>T p.C283F | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV100792601; called by muse, mutect2, varscan2
- FLVCR1 | c.1169T>C p.L390S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV100875045; called by muse, mutect2, varscan2
- FRMPD3 | c.4051C>T p.P1351S | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.041); catalogued as COSV99346370; called by muse, mutect2
- FRY | c.341G>T p.S114I | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100969318; called by muse, mutect2, varscan2
- GFOD2 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99263498, COSV99263562; called by muse, mutect2, varscan2
- H2BC12 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.325); catalogued as COSV100804681, COSV63616685; called by muse, mutect2, varscan2
- HSPA8 | c.482C>A p.A161D | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV99914414; called by muse, mutect2, varscan2
- IRF6 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100883982; called by muse, mutect2, varscan2
- KCNK2 | c.650G>A p.S217N (on ENST00000444842 / NM_001017425.3; = p.S202N on NM_014217.4) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as rs761268527, COSV101222168; called by muse, mutect2, varscan2
- KIF20B | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99590067; called by muse, mutect2
- KIF20B | c.4636G>A p.E1546K (on ENST00000371728 / NM_001284259.2; = p.E1506K on NM_016195.4) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99590070; called by muse, mutect2, varscan2
- KIF20B | c.5033C>G p.T1678S (on ENST00000371728 / NM_001284259.2; = p.T1638S on NM_016195.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99590072; called by muse, mutect2, varscan2
- KIR2DL1 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV99383124; called by muse, mutect2, varscan2
- KRT6B | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as rs1190770992, COSV52882653, COSV99360759; called by muse, varscan2
- LAMA1 | c.4646T>C p.M1549T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.05); catalogued as rs778892342, COSV101056507; called by mutect2, varscan2
- LARS1 | c.918G>T p.W306C (on ENST00000394434 / NM_020117.11; = p.W279C on NM_016460.3) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99198616; called by muse, mutect2, varscan2
- LRRC3B | c.20G>A p.W7* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | catalogued as COSV101185889; called by muse, mutect2, varscan2
- LRSAM1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.98); catalogued as COSV55940065; called by muse, mutect2, varscan2
- LTBP4 | c.1768G>A p.E590K (on ENST00000308370 / NM_001042544.1; = p.E553K on NM_003573.2) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV99192835; called by muse, mutect2, varscan2
- M1AP | c.486G>C p.L162F | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99303968, COSV99304118; called by muse, varscan2
- MAN2C1 | c.3043C>T p.R1015W | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as rs139418901; called by muse, mutect2, varscan2
- MAP3K10 | c.1717G>C p.E573Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); catalogued as COSV99454422; called by muse, mutect2, varscan2
- MCM8 | c.2008A>G p.I670V | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.061); catalogued as rs766334803, COSV99495693; called by muse, mutect2, varscan2
- MCTP2 | c.962A>G p.K321R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.788); catalogued as COSV100537488; called by muse, mutect2
- MRPS5 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99720841; called by muse, mutect2, varscan2
- MTMR11 | c.343G>T p.V115F (on ENST00000439741 / NM_001145862.2; = p.V43F on NM_181873.3) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100809015; called by muse, mutect2, varscan2
- MUC16 | c.25873G>A p.E8625K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs1261298838, COSV101200017; called by muse, mutect2, varscan2
- MUC5B | c.14789G>A p.R4930K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as rs1192845660, COSV101500378; called by muse, mutect2, varscan2
- MYH13 | c.296A>C p.E99A | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99354142; called by muse, mutect2
- NAALAD2 | c.273G>T p.K91N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as COSV100428466; called by muse, mutect2, varscan2
- NF1 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.795); catalogued as COSV100647142, COSV62222474; called by muse, mutect2, varscan2
- NFE2L3 | c.1397G>A p.G466D | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs765762057, COSV99283734; called by muse, mutect2, varscan2
- NLRP14 | c.1877G>T p.R626L | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100205024; called by muse, mutect2, varscan2
- NME5 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs540788174, COSV99496682; called by muse, mutect2, varscan2
- NR2F2 | c.511C>G p.P171A | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV101241036; called by muse, mutect2
- NUFIP2 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.568); catalogued as COSV56604566; called by muse, mutect2, varscan2
- OPA1 | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV100655334; called by muse, mutect2, varscan2
- OR1L1 | c.750G>C p.M250I (on ENST00000373686; = p.M200I on NM_001005236.3) | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV100542182; called by muse, mutect2, varscan2
- OTOL1 | c.290T>A p.F97Y | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.813); catalogued as COSV100020017; called by muse, mutect2, varscan2
- OTULIN | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99419767; called by muse, mutect2, varscan2
- PCDHB15 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV99178944; called by muse, mutect2, varscan2
- PCDHB8 | c.1436G>A p.R479K | Missense Mutation (SNP) | VAF 58/502 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.41); catalogued as COSV99176983; called by muse, mutect2, varscan2
- PCDHGC5 | c.617C>G p.A206G | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV99340287; called by muse, mutect2, varscan2
- PDE3B | c.2065G>T p.G689* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99962620; called by muse, mutect2, varscan2
- PDE3B | c.2066G>T p.G689V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56389738, COSV99962621; called by muse, mutect2, varscan2
- PGAM2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs144070530; called by muse, varscan2
- PGAM2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.127); catalogued as rs1426478791, COSV99803451; called by muse, varscan2
- PIEZO2 | c.6708G>A p.M2236I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99555021; called by muse, mutect2, varscan2
- PIWIL3 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as COSV100177659; called by muse, mutect2, varscan2
- PLCL1 | c.3119T>C p.L1040P | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101406991; called by muse, mutect2, varscan2
- PLEKHM3 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV101216595; called by muse, mutect2, varscan2
- PLIN2 | c.30+1G>C p.X10_splice | Splice Site (SNP) | VAF 30/75 reads (40%) | catalogued as COSV99438939; called by muse, mutect2, varscan2
- PON3 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 12/138 reads (9%) | catalogued as rs1246571437, COSV99672507; called by muse, mutect2
- PRDM10 | c.2418G>T p.K806N | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100456600, COSV100456804; called by muse, mutect2, varscan2
- PRMT8 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 19/209 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99713416; called by muse, mutect2
- PRPS2 | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 97/210 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV101037599, COSV66179403; called by muse, mutect2, varscan2
- PSMD1 | c.2313C>G p.F771L | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV100433624; called by muse, mutect2
- PTPRZ1 | c.6016C>G p.H2006D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101100155; called by muse, mutect2, varscan2
- RALGAPA2 | c.1241T>A p.L414* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV99173647; called by muse, mutect2, varscan2
- RANBP17 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV101206282; called by muse, mutect2, varscan2
- RBM27 | c.724G>T p.V242L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV99506191; called by muse, mutect2, varscan2
- RELN | c.5095G>A p.E1699K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs147657490; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFFL | c.982C>G p.L328V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52073273, COSV99265344; called by muse, mutect2, varscan2
- RIC1 | c.2884C>G p.L962V | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471122411, COSV52604855, COSV99317759; called by muse, mutect2, varscan2
- RNF141 | c.433A>T p.R145W | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV99792907; called by muse, mutect2, varscan2
- RNF40 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs556209638, COSV100221925, COSV100222110; called by muse, mutect2, varscan2
- RNFT2 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773879049, COSV99985305; called by muse, mutect2, varscan2
- RPS6KB2 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100321997; called by muse, mutect2, varscan2
- RYR2 | c.9823A>T p.T3275S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV100770435; called by muse, varscan2
- SCAND1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV100018926; called by muse, mutect2, varscan2
- SEPTIN3 | c.1009C>G p.P337A | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.22); catalogued as COSV99352022, COSV99352144; called by muse, mutect2, varscan2
- SERPINB4 | c.957G>C p.W319C | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs1359361019, COSV100345722; called by muse, mutect2
- SLC24A3 | c.1736G>A p.R579K | Missense Mutation (SNP) | VAF 15/496 reads (3%) | SIFT tolerated (0.95); PolyPhen benign (0.035); catalogued as rs1465480836, COSV60123716; called by muse, mutect2
- SLC38A1 | c.932C>G p.S311* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV101284192; called by muse, mutect2
- SMPDL3A | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs772991613, COSV100868701; called by muse, mutect2, varscan2
- SNU13 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99316814; called by muse, mutect2
- SPANXN2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.545); catalogued as COSV100979897; called by muse, varscan2
- SPTBN2 | c.3094C>T p.Q1032* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as COSV59460048; called by muse, mutect2
- ST18 | c.1685G>T p.S562I | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV99389746; called by muse, mutect2, varscan2
- SYT13 | c.1169T>A p.L390H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99194725; called by muse, mutect2, varscan2
- TAS2R14 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101114889; called by muse, mutect2, varscan2
- TECTB | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 65/114 reads (57%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs1241922062, COSV101027707; called by muse, mutect2, varscan2
- TGFB1 | c.273G>C p.E91D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV99699150; called by muse, mutect2, varscan2
- THADA | c.4765G>C p.E1589Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.143); catalogued as rs1186943213, COSV100368690, COSV57682675; called by muse, mutect2, varscan2
- THBS4 | c.1955T>A p.L652Q | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV100644280; called by muse, mutect2, varscan2
- TRRAP | c.3241G>C p.E1081Q | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100722517; called by muse, mutect2, varscan2
- TTBK1 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52488232, COSV99445318; called by mutect2, varscan2
- TUBA3D | c.989C>G p.A330G | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV100342595; called by muse, mutect2, varscan2
- UBE4A | c.2188G>T p.E730* (on ENST00000252108 / NM_001204077.2; = p.E737* on NM_004788.4) | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | catalogued as COSV52803940, COSV99348244; called by muse, varscan2
- UBR5 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as COSV99640949; called by muse, mutect2
- USP1 | c.2201C>T p.S734L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99224590; called by muse, mutect2, varscan2
- VWA3A | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100240929; called by muse, varscan2
- WNK4 | c.2555C>G p.S852* | Nonsense Mutation (SNP) | VAF 17/159 reads (11%) | catalogued as COSV99890409; called by muse, mutect2, varscan2
- WSB2 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100199326; called by muse, mutect2, varscan2
- XRRA1 | c.839C>A p.S280* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100369868; called by muse, mutect2, varscan2
- ZNF181 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as COSV67627319; called by muse, mutect2
- ZNF208 | c.1375G>T p.G459C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101237031; called by muse, mutect2, varscan2
- ZNF285 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100450014, COSV58408249; called by muse, mutect2, varscan2
- ZNF319 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs767202477, COSV54622641; called by muse, varscan2
- ZNF43 | c.1265G>C p.G422A | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100731631; called by muse, mutect2, varscan2
- ZNF548 | c.767G>C p.R256T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.078); catalogued as COSV100278157; called by muse, mutect2
- ZNF747 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99411535; called by muse, mutect2, varscan2
- HMOX2 | c.421_423del p.I141del | In Frame Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- MDH1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.247); called by muse, mutect2
- PCDHGB5 | c.958G>C p.G320R | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- PIGN | c.228_229insT p.I77Yfs*4 | Frame Shift Ins (INS) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- ZNF563 | c.541_551del p.R181Sfs*11 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- ADCY1 | c.700C>T p.L234= | Silent (SNP) | VAF 59/185 reads (32%) | catalogued as rs1230390578, COSV99812073; called by muse, mutect2, varscan2
- ANPEP | c.729G>A p.L243= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as rs748571712, COSV100263100; called by muse, mutect2, varscan2
- APBA1 | c.1302A>G p.R434= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99596154; called by muse, mutect2, varscan2
- ATP13A5 | c.648T>A p.T216= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as COSV100665181; called by muse, mutect2, varscan2
- BTN3A1 | c.798C>T p.A266= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs771170154, COSV50024863, COSV99175608; called by muse, mutect2, varscan2
- BUB1B | c.261G>A p.Q87= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV99806947; called by muse, mutect2
- C4B | c.3516C>T p.I1172= | Silent (SNP) | VAF 19/150 reads (13%) | catalogued as COSV101312244; called by muse, mutect2, varscan2
- CAPN3 | c.444C>T p.V148= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as COSV100533035; called by muse, mutect2, varscan2
- CHGB | c.183G>A p.L61= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as rs1363783047, COSV100972966; called by muse, mutect2, varscan2
- CPT1A | c.261C>A p.I87= | Silent (SNP) | VAF 81/139 reads (58%) | catalogued as COSV99681188; called by muse, mutect2, varscan2
- CPT2 | c.1239G>A p.Q413= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as CD991686, CM110478, COSV99598152; called by muse, mutect2, varscan2
- CROCC | c.3234G>A p.L1078= | Silent (SNP) | VAF 31/196 reads (16%) | catalogued as COSV100978249; called by muse, mutect2, varscan2
- ECT2 | c.423C>G p.L141= (on ENST00000392692 / NM_001349098.2; = p.L110= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/197 reads (6%) | catalogued as COSV51694880, COSV99221394; called by muse, mutect2
- EEF1G | c.1104C>T p.S368= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs1299980296, COSV100240393; called by muse, mutect2, varscan2
- EXOSC2 | c.105G>A p.T35= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV100964258; called by muse, mutect2, varscan2
- FBXO40 | c.1224C>G p.L408= | Silent (SNP) | VAF 8/176 reads (5%) | catalogued as COSV100573185; called by muse, mutect2
- FCRL3 | c.864G>A p.V288= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV63839005; called by muse, mutect2, varscan2
- FGA | c.1644C>A p.G548= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as rs368704885, COSV100120400; called by muse, mutect2, varscan2
- FNDC1 | c.3732C>T p.L1244= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1355099818; called by muse, mutect2
- FOXG1 | c.522G>A p.K174= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV57397141, COSV57399108; called by muse, mutect2
- FZR1 | c.402C>T p.T134= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as COSV100553623; called by muse, mutect2, varscan2
- GNL1 | c.873G>C p.L291= | Silent (SNP) | VAF 52/259 reads (20%) | catalogued as COSV100925423; called by muse, mutect2, varscan2
- GOLGA7B | c.93C>T p.T31= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs1040054896, COSV101002375; called by muse, mutect2, varscan2
- GSDMA | c.1116G>A p.Q372= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV99227835; called by muse, mutect2, varscan2
- HAP1 | c.1929G>A p.L643= (on ENST00000310778 / NM_001367460.1; = p.L591= on NM_177977.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/195 reads (23%) | catalogued as rs782491628, COSV100169704; called by muse, mutect2, varscan2
- IL18RAP | c.591C>A p.L197= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99962007; called by muse, mutect2, varscan2
- INSIG1 | c.51G>A p.A17= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100453000; called by muse, mutect2, varscan2
- IRF6 | c.609C>T p.P203= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100883983; called by muse, varscan2
- IRF7 | c.912G>C p.V304= (on ENST00000397566; = p.V291= on NM_001572.5) | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99200658; called by muse, mutect2
- KCNB1 | c.1773C>T p.F591= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs1299308025, COSV100870474; called by muse, mutect2, varscan2
- KCND2 | c.1203T>A p.P401= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100476088; called by muse, mutect2, varscan2
- KCNH8 | c.2388G>A p.L796= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV100109152; called by muse, mutect2, varscan2
- KIF13A | c.1131G>A p.L377= | Silent (SNP) | VAF 22/278 reads (8%) | catalogued as COSV52441356; called by muse, mutect2
- LRP1B | c.10254G>A p.G3418= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs777513301, COSV101257489; called by muse, mutect2, varscan2
- MED16 | c.423G>A p.V141= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99515669; called by muse, mutect2, varscan2
- MMP28 | c.771C>T p.L257= | Silent (SNP) | VAF 5/27 reads (19%) | called by mutect2, varscan2
- MPP2 | c.1662C>T p.R554= (on ENST00000461854 / NM_001278372.2; = p.R530= on NM_005374.5) | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs374802065; called by muse, mutect2, varscan2
- MUC3A | c.8040C>A p.I2680= | Silent (SNP) | VAF 59/870 reads (7%) | catalogued as COSV100114644; called by muse, mutect2
- OSBP2 | c.378G>A p.P126= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs765653023, COSV100213202; called by mutect2, varscan2
- PDE2A | c.2295C>T p.I765= | Silent (SNP) | VAF 7/137 reads (5%) | catalogued as COSV100558011; called by muse, mutect2
- PEG3 | c.1732C>T p.L578= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs202126306, COSV99689077; called by muse, mutect2, varscan2
- PIK3R5 | c.1821C>T p.I607= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV99353391; called by muse, mutect2
- PMVK | c.195C>T p.T65= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as rs1384778174, COSV100870513; called by muse, mutect2, varscan2
- POU2F1 | c.717G>A p.S239= (on ENST00000541643 / NM_001365848.1; = p.S262= on NM_002697.4) | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs149991945, COSV54812217; called by muse, mutect2, varscan2
- PPP1R12A | c.1338T>C p.Y446= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV99700422; called by muse, mutect2, varscan2
- PRKCSH | c.1272C>G p.V424= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as COSV99371629; called by muse, mutect2
- PRUNE2 | c.7782C>T p.F2594= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV100944172; called by muse, mutect2
- RETREG3 | c.1293C>A p.L431= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99518960; called by muse, mutect2
- RPS6KA2 | c.111C>T p.V37= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs776375679, COSV99690948; called by muse, mutect2, varscan2
- SDAD1 | c.1503T>C p.S501= | Silent (SNP) | VAF 10/131 reads (8%) | catalogued as COSV100668622; called by muse, mutect2
- SEMA3D | c.1347G>A p.L449= | Silent (SNP) | VAF 21/183 reads (11%) | catalogued as COSV99406692; called by muse, mutect2, varscan2
- SOWAHC | c.1152G>T p.R384= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs1558940989, COSV100454104; called by muse, varscan2
- SOX2 | c.351G>A p.K117= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV100327199; called by muse, mutect2
- SPTA1 | c.1641T>C p.H547= | Silent (SNP) | VAF 21/212 reads (10%) | catalogued as rs35932551; called by muse, mutect2
- SSH1 | c.1590C>A p.V530= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV100425557; called by muse, mutect2, varscan2
- STK17A | c.807A>G p.Q269= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs1252757238, COSV100082170; called by muse, mutect2, varscan2
- TP63 | c.477C>A p.L159= | Silent (SNP) | VAF 110/156 reads (71%) | catalogued as COSV99287013; called by muse, mutect2, varscan2
- TTC17 | c.927G>T p.G309= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV99235354; called by muse, mutect2
- TTN | c.18537T>C p.S6179= (on ENST00000591111; = p.S5252= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV59935137; called by muse, mutect2
- XKR3 | c.942T>C p.Y314= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as COSV100509275; called by muse, mutect2, varscan2
- ZNF260 | c.969G>C p.V323= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV101591060, COSV72951152; called by muse, mutect2
- ZNF571 | c.1629A>G p.S543= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV100143780; called by muse, mutect2, varscan2
- ZNF774 | c.639G>A p.E213= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100586346; called by muse, mutect2, varscan2
- C14orf177 | n.571_572del | RNA (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- COL11A1 | c.898-229G>A | Intron (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100616668; called by muse, mutect2, varscan2
- SNORD114-15 | n.44G>A | RNA (SNP) | VAF 18/125 reads (14%) | called by muse, mutect2, varscan2
